Gene-level copy-number profile of tumor specimen TARGET-40-PATPBS-01A from TARGET case TARGET-40-PATPBS, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 15.1 years (5,513 days).
Specimen TARGET-40-PATPBS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.feab8d41-9999-57aa-8494-c18bec914b67.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PATPBS-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 401 have no estimate.
https://portal.gdc.cancer.gov/files/c16d429b-cf8e-47cc-a6bb-256eedcd7b77

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 464; copy number 1: 4,499; copy number 2: 12,659; copy number 3: 18,380; copy number 4: 14,822; copy number 5: 4,733; copy number 6: 3,564; copy number 7: 424; copy number 8: 461; copy number 9: 97; copy number 10: 93; copy number 11: 1; copy number 12: 25.

Homozygous deletions (total copy number 0; autosomes only): 23 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:241,881,363–242,078,722, 1 gene (within-gene range 0–1): LINC01237.
- chr2:242,001,209–242,160,153, 8 genes: AC093642.3, AC093642.1, AC093642.6, LINC01880, AC093642.2, LINC01881, CICP10, SEPTIN14P2.
- chr3:116,850,277–117,027,039, 5 genes: MIR4447, AC069504.1, LINC00901, RNU5E-8P, PTMAP8.
- chr5:165,349,030–166,155,439, 6 genes: AC008415.1, RN7SKP60, AC008562.1, AC008489.1, RPL7P20, AC114321.1.
- chr8:6,473,845–6,474,288, 1 gene: AC016065.2.
- chr11:55,635,113–55,652,854, 2 genes: OR4P4, OR4S2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 581 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:157,830,911–170,553,834, 368 genes, copy number 7–8 (broad region; genes not listed).
- chr1:181,668,749–181,669,028, 1 gene, copy number 7: Metazoa_SRP.
- chr2:88,811,186–88,861,563, 1 gene, copy number 12 (within-gene range 4–12): AC244205.1.
- chr2:88,857,161–89,117,844, 24 genes, copy number 12: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17.
- chr5:55,838,801–57,899,162, 44 genes, copy number 7–8: HNRNPH1P3, IL31RA, IL6ST, AC008914.1, AC016596.2, AC008892.1, FLJ31104, AC016596.1, ANKRD55, RNU6-299P, RPL17P22, RNA5SP184, C1GALT1P2, RNA5SP185, PSMC1P4, RNU6ATAC2P, AC034245.1, HMGN1P17, LINC01948, AC008391.1, RPL26P19, C5orf67, AC022431.1, AC008940.1, MAP3K1, AC008937.2, AC008937.1, SETD9, MIER3, AC008937.3, AC016644.1, AC114973.1, AC034244.1, AC034244.2, Y_RNA, GPBP1, AC025470.1, AC025470.2, SALL4P1, ACTBL2, LINCR-0003, AC008780.1, AC106822.1, LINC02225.
- chr10:3,009,976–3,013,111, 1 gene, copy number 11 (within-gene range 4–11): AL731533.1.
- chr12:32,679,200–34,249,958, 32 genes, copy number 7: DNM1L, AC084824.2, Y_RNA, AC084824.5, AC084824.1, YARS2, AC084824.3, AC084824.4, AC087588.2, PKP2, AC087588.1, RPL35AP27, ASS1P14, AC087311.1, SYT10, AC023158.1, AC023158.2, AC016956.1, RNU6-400P, AC024153.1, RNU6-472P, Y_RNA, AC046130.1, ALG10, AC046130.2, AC140847.1, AC140847.3, TUBB8P4, AC140847.2, RNA5SP357, DUX4L27, AK6P1.
- chr13:53,028,813–53,052,057, 1 gene, copy number 7: OLFM4.
- chr13:62,406,058–63,513,393, 6 genes, copy number 7: SQSTM1P1, AL445668.1, LINC00448, AL354810.1, LINC00376, AL359208.1.
- chr14:32,329,298–33,804,176, 6 genes, copy number 7 (within-gene range 5–7): AKAP6, AL136298.1, RN7SL660P, MTCO1P2, AL049781.1, NPAS3.
- chr14:105,785,505–106,344,833, 97 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,313. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
